Gene-level copy-number profile of tumor specimen TCGA-AX-A1CR-01A from TCGA case TCGA-AX-A1CR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 70.7 years (25,812 days).
Specimen TCGA-AX-A1CR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.2c852ae6-d223-4737-a41d-c5794f9af73e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A1CR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c707a644-60dd-4559-9837-506540924ebd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 393; copy number 2: 17,430; copy number 3: 9,857; copy number 4: 27,865; copy number 5: 2,378; copy number 6: 925; copy number 7: 800; copy number 8: 24; copy number 9: 82; copy number 10: 1; copy number 13: 5; copy number 14: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AX-A1CR-01): tumor purity 0.7, ploidy 3.42, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr3:17,465,150–17,465,510, 1 gene: AC140076.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 121 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:168,858,659–169,038,416, 5 genes, copy number 13: RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997.
- chr12:56,316,223–56,688,408, 22 genes, copy number 9 (within-gene range 4–9): PAN2, IL23A, STAT2, RNU7-40P, APOF, APONP, AC025574.1, AC024884.2, AC024884.1, TIMELESS, MIP, AC097104.1, SPRYD4, GLS2, HSPD1P4, RBMS2, RNU6-343P, BAZ2A, ATP5F1B, SNORD59A, PTGES3, RN7SL809P.
- chr19:12,891,160–12,914,207, 1 gene, copy number 9 (within-gene range 5–9): GCDH.
- chr19:12,898,786–13,158,788, 24 genes, copy number 9: SYCE2, MIR5695, FARSA, FARSA-AS1, CALR, MIR6515, AC092069.1, RAD23A, GADD45GIP1, DAND5, NFIX, AC138474.1, AC007787.1, AC007787.2, LYL1, TRMT1, NACC1, AC005546.1, AC011446.1, STX10, IER2, AC011446.3, AC011446.2, RPL12P42.
- chr19:44,417,519–44,993,341, 34 genes, copy number 10–14 (within-gene range 7–14): ZNF229, ZNF285B, ZNF180, CEACAM20, AC245748.3, CEACAM22P, AC243964.1, IGSF23, AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, AC092306.1, BCAM, NECTIN2, AC011481.2, TOMM40, APOE, AC011481.3, APOC1, APOC1P1, APOC4, APOC4-APOC2, APOC2, AC011481.1, CLPTM1.
- chr20:63,743,668–63,832,038, 1 gene, copy number 9 (within-gene range 6–9): ZBTB46.
- chr20:63,808,076–64,313,132, 34 genes, copy number 9: ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 393. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
